Somatic mutation profile of tumor specimen TCGA-B5-A11E-01A (aliquot TCGA-B5-A11E-01A-11D-A10M-09) from TCGA case TCGA-B5-A11E, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 53.3 years (19,458 days).
Specimen TCGA-B5-A11E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87a14cc7-18ef-4e1e-be71-50f7499095c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11E-10A (Blood Derived Normal), aliquot TCGA-B5-A11E-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77f57cf-0a4e-4b6c-9a30-31db3989b594

The open-access MAF lists 11,075 somatic variants for this specimen: 8,261 protein-altering or splice-affecting, 2,617 silent, 197 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,415, Silent 2,617, Nonsense Mutation 599, Splice Site 127, Intron 86, Splice Region 67, RNA 55, 3'UTR 24, Frame Shift Ins 22, Frame Shift Del 17, 3'Flank 15, 5'UTR 8.

Variants (750 of 11,075; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781617345, CM073984, COSV56848476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, varscan2
- ATM | c.6100C>T p.R2034* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs532480170, CM960102, COSV53736160; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 93/279 reads (33%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, varscan2
- BRCA1 | c.4327C>T p.R1443* | Nonsense Mutation (SNP) | VAF 52/121 reads (43%) | catalogued as rs41293455, CM940179, CM940180, COSV58787462; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.6373dup p.T2125Nfs*4 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | catalogued as rs80359577; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1F | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs797044676, CM010174, COSV59903636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773001194, CM990305, COSV58820875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CASK | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1114167352, COSV59364220; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- CPLANE1 | c.*2776C>T | 3'UTR (SNP) | VAF 37/95 reads (39%) | catalogued as rs749421099, COSV57056397; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CPT2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368311455, CM065093; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1579C>T p.R527C (on ENST00000399959; = p.R528C on NM_001356.5) | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1064795323, COSV67863221; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.10262C>T p.A3421V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs104894791, CM940364, COSV58902399; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- EYS | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as rs794727631, CM1211748, COSV60981344; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); catalogued as rs1340793072, COSV71673166; called by muse, mutect2, varscan2
- FBN1 | c.6697C>T p.P2233S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs794728255, COSV57313456; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FLVCR2 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs757778790, COSV53161779; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- GFAP | c.1366C>T p.R456W (on ENST00000253408 / NM_001363846.2; = p.R416W on NM_002055.5) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs121909717, CM010052, COSV53649837; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- GYS2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as rs267603422, COSV53921842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IARS2 | c.2620G>A p.G874R | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs151241066; ClinVar: pathogenic; called by muse, varscan2
- INS-IGF2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs121908260, CM082896, COSV99171120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs776681643, COSV55391670, COSV99855011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2B | c.7759C>T p.R2587* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs1555734923, COSV53073648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/114 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 41/77 reads (53%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 89/184 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MEF2C | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as rs796052733, COSV60928469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MSTO1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749922789, COSV55471710; ClinVar: pathogenic; called by muse, varscan2
- MVK | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as rs758026399, CM142907, COSV57331591; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYOM1 | c.4987G>A p.V1663M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751200138, CM155525, COSV55288777; ClinVar: likely pathogenic; called by muse, varscan2
- OCRL | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853263, CM050304, COSV63980555; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs62642945, CM961079, COSV100188508, COSV61015366; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- PBX1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs1553248081, COSV63342742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 26/82 reads (32%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PKP2 | c.2484C>T p.G828= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs727504509, CS065607, COSV50728278; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PTCH1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 39/79 reads (49%) | catalogued as rs863224650, CM066203, COSV59462369, COSV59487305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660634, CM094222, COSV64293993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 53/120 reads (44%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs772468452, COSV54749843, COSV99529486; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs121909742, CM971383, COSV58585414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC30A2 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs185398527, CM127908, CM1312262, COSV65332522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs387906759, CM115709, COSV61189771; ClinVar: pathogenic; called by muse, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, mutect2
- TELO2 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754162070, CM166747, COSV51976862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TJP2 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as rs746830415, COSV55265049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TLK2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | catalogued as rs1567920209, COSV58297927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC22D2 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912473665, COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- TTN | c.7516C>T p.R2506* (on ENST00000591111; = p.R2460* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as rs780415493, COSV100598961; ClinVar: likely pathogenic; called by muse, mutect2
- TYR | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs28940878, CM910379, COSV99633357; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV55288675, COSV55301101; called by muse, mutect2, varscan2
- AAAS | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs763760167, COSV52932604; called by muse, mutect2, varscan2
- AACS | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765091999, COSV55535753; called by muse, mutect2, varscan2
- AAK1 | c.2354C>A p.P785H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV68642984; called by muse, mutect2, varscan2
- AAMDC | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV59017267; called by muse, mutect2, varscan2
- AAMP | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50307241; called by muse, mutect2, varscan2
- AARS2 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55114196, COSV55116521; called by muse, mutect2, varscan2
- AASDH | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV52705491; called by muse, mutect2, varscan2
- ABCA10 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV52220389; called by muse, mutect2, varscan2
- ABCA13 | c.14879A>C p.E4960A | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV68945302; called by muse, varscan2
- ABCA3 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57051868; called by muse, mutect2, varscan2
- ABCA4 | c.3922G>A p.E1308K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1485892324, COSV100933050; called by muse, mutect2
- ABCA4 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs548888187, COSV64672582; called by muse, mutect2, varscan2
- ABCA5 | c.4485G>T p.E1495D | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67016280; called by muse, mutect2, varscan2
- ABCA5 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as COSV67016284; called by muse, mutect2, varscan2
- ABCA5 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as rs1328374477, COSV67016285; called by muse, mutect2, varscan2
- ABCA6 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs748120631, COSV52637254; called by muse, mutect2, varscan2
- ABCA7 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV54027192; called by muse, mutect2, varscan2
- ABCA8 | c.4214C>T p.S1405L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754538890, COSV52198308; called by muse, varscan2
- ABCA8 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.074); catalogued as COSV52198323; called by muse, mutect2, varscan2
- ABCB1 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.519); catalogued as COSV55948482; called by muse, mutect2, varscan2
- ABCB10 | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV60620567; called by muse, mutect2, varscan2
- ABCB4 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV55933950; called by muse, mutect2, varscan2
- ABCB5 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as rs753647911, COSV51706888; called by muse, mutect2, varscan2
- ABCB9 | c.1604C>T p.T535M (on ENST00000280560 / NM_019625.4; = p.T492M on NM_019624.3) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1410076544, COSV54891082; called by muse, mutect2, varscan2
- ABCB9 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV54891093; called by muse, mutect2, varscan2
- ABCC1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs761595745; called by muse, mutect2
- ABCC1 | c.1873C>A p.L625M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60683342; called by muse, mutect2, varscan2
- ABCC2 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755485165, COSV64984961; called by muse, mutect2, varscan2
- ABCC3 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV53319457; called by muse, mutect2, varscan2
- ABCC3 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567833577, COSV53319481; called by muse, mutect2, varscan2
- ABCC4 | c.3052G>T p.D1018Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV65311173; called by muse, mutect2, varscan2
- ABCC4 | c.2848G>A p.V950I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as rs753708057, COSV65311180; called by muse, mutect2, varscan2
- ABCC4 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1345176162, COSV65311190; called by muse, mutect2, varscan2
- ABCC5 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55588816; called by muse, mutect2, varscan2
- ABCC8 | c.4409T>G p.L1470R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as CD131783, COSV56848464; called by muse, mutect2, varscan2
- ABCC8 | c.4054C>T p.R1352C | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434876771, COSV56852264; called by muse, mutect2
- ABCC8 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56848469; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, mutect2, varscan2
- ABCC9 | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53966966; called by muse, mutect2, varscan2
- ABCD1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs782723351, COSV54383490; called by muse, mutect2, varscan2
- ABCD3 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59865737; called by muse, varscan2
- ABCD3 | c.1871C>A p.S624Y | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64642762; called by muse, mutect2, varscan2
- ABCF1 | c.2104C>T p.R702C (on ENST00000326195 / NM_001025091.2; = p.R664C on NM_001090.3) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs1409283635, COSV58228640; called by muse, mutect2, varscan2
- ABCG2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755591361, COSV52944852; called by muse, mutect2, varscan2
- ABCG8 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs200005264, COSV55391981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD12 | c.1030-1G>T p.X344_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV53817301; called by muse, mutect2, varscan2
- ABHD17B | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs372210485, COSV61007519; called by muse, mutect2, varscan2
- ABHD18 | c.122A>T p.N41I | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV66293534; called by muse, varscan2
- ABHD18 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66293540; called by muse, varscan2
- ABHD3 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs142326991; called by muse, mutect2, varscan2
- ABHD4 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202089812, COSV53529534; called by muse, mutect2, varscan2
- ABHD5 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV50006356; called by muse, mutect2, varscan2
- ABI3BP | c.2255G>T p.R752I | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52532783; called by muse, mutect2, varscan2
- ABL2 | c.3490C>T p.P1164S (on ENST00000502732 / NM_007314.4; = p.P1149S on NM_005158.5) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.338); catalogued as rs199707055, COSV100772540; called by muse, varscan2
- ABLIM1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs768481591, COSV53303406; called by muse, mutect2, varscan2
- ABO | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV101505941; called by muse, mutect2, varscan2
- ABR | c.347C>T p.P116L (on ENST00000302538 / NM_021962.5; = p.P79L on NM_001092.5) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV52144191; called by muse, mutect2, varscan2
- ABRA | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100357489; called by muse, mutect2
- ABRAXAS2 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as rs199511821, COSV53716573; called by muse, mutect2, varscan2
- AC002094.3 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.028); catalogued as COSV52646323; called by muse, mutect2, varscan2
- AC006059.2 | c.2101C>A p.L701M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV59606393; called by muse, mutect2, varscan2
- AC006059.2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 107/283 reads (38%) | catalogued as COSV59606400; called by muse, mutect2, varscan2
- AC011448.1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs776300867, COSV52273855; called by muse, mutect2, varscan2
- AC023055.1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as rs544589772, COSV60242962; called by muse, mutect2, varscan2
- AC024940.1 | n.2467G>A | Splice Region (SNP) | VAF 33/91 reads (36%) | catalogued as rs1363745674; called by muse, mutect2, varscan2
- AC090517.4 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV50996308; called by muse, mutect2, varscan2
- AC092143.1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59248011; called by muse, mutect2
- AC092718.8 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV59601543; called by muse, mutect2, varscan2
- AC104452.1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs929879659, COSV56469305; called by muse, mutect2, varscan2
- AC126283.2 | c.1426A>C p.K476Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV67098239; called by muse, mutect2, varscan2
- AC131160.1 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as COSV57700403; called by muse, mutect2, varscan2
- AC136428.1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV71169100; called by muse, mutect2, varscan2
- ACAD8 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV55539778; called by muse, mutect2, varscan2
- ACAD9 | c.453+1G>A p.X151_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV58307061; called by muse, varscan2
- ACADM | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as CM128327, COSV63720094; called by muse, mutect2, varscan2
- ACADVL | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794727111, COSV50035059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.4342A>G p.I1448V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.051); catalogued as COSV61358676; called by muse, mutect2, varscan2
- ACAP1 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV50134744; called by muse, mutect2, varscan2
- ACAP2 | c.1685A>G p.D562G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV58750933; called by muse, mutect2, varscan2
- ACBD3 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV64729958; called by muse, mutect2, varscan2
- ACBD3 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64729967; called by muse, mutect2, varscan2
- ACBD3 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs763517769, COSV100830871; called by muse, varscan2
- ACBD3 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs147538215; called by muse, varscan2
- ACCS | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs758423933, COSV55457716; called by muse, mutect2, varscan2
- ACE | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770340552, COSV99326550; called by muse, mutect2
- ACE2 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV53024390; called by muse, mutect2, varscan2
- ACE2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024399; called by muse, mutect2, varscan2
- ACE2 | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53024421; called by muse, varscan2
- ACER2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs373757954; called by muse, mutect2, varscan2
- ACKR1 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV63672400, COSV63674323; called by muse, mutect2, varscan2
- ACLY | c.2410C>A p.L804I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61250077; called by muse, mutect2, varscan2
- ACOX1 | c.1413G>A p.W471* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53132442; called by muse, mutect2, varscan2
- ACOX2 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs376964394; called by muse, mutect2, varscan2
- ACOX2 | c.582C>T p.D194= | Splice Region (SNP) | VAF 30/68 reads (44%) | catalogued as rs1290571422, COSV57148266; called by muse, mutect2, varscan2
- ACOXL | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs762071917, COSV61323479; called by muse, mutect2, varscan2
- ACP7 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58698744; called by muse, mutect2, varscan2
- ACRV1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV59754740; called by muse, mutect2, varscan2
- ACSBG1 | c.2169A>C p.K723N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.327); catalogued as COSV51904798; called by muse, mutect2, varscan2
- ACSBG2 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53123825; called by muse, mutect2, varscan2
- ACSL1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200209968, COSV55661706; called by muse, mutect2, varscan2
- ACSL1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs200100894, COSV55661716; called by muse, mutect2, varscan2
- ACSL4 | c.914G>T p.R305I (on ENST00000340800 / NM_022977.2; = p.R264I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV61613766; called by muse, mutect2, varscan2
- ACSL4 | c.196G>A p.D66N (on ENST00000340800 / NM_022977.2; = p.D25N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs1363259105, COSV61613928; called by muse, mutect2, varscan2
- ACSL5 | c.637G>A p.D213N (on ENST00000354273; = p.D269N on NM_016234.3) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs865991936, COSV61129861; called by muse, mutect2, varscan2
- ACSL5 | c.767G>A p.S256N (on ENST00000354273; = p.S312N on NM_016234.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV61129874; called by muse, mutect2, varscan2
- ACSL5 | c.1408G>A p.A470T (on ENST00000354273; = p.A526T on NM_016234.3) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61129883; called by muse, varscan2
- ACSL6 | c.1295T>C p.V432A (on ENST00000379240; = p.V457A on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV57296522; called by muse, mutect2, varscan2
- ACSM1 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54634465; called by muse, mutect2, varscan2
- ACSM2A | c.833C>G p.A278G (on ENST00000219054; = p.A199G on NM_001308169.2) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54583655; called by muse, mutect2, varscan2
- ACSM2B | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV61656870, COSV61658390; called by muse, mutect2, varscan2
- ACSM3 | c.1561A>C p.K521Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55500765; called by muse, mutect2, varscan2
- ACSM5 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59370502; called by muse, mutect2
- ACSS1 | c.1707+1G>A p.X569_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as rs781013294, COSV100053249; called by muse, mutect2
- ACSS3 | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698404; called by muse, mutect2
- ACTA2 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV56516077; called by muse, mutect2, varscan2
- ACTL6A | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV66998839; called by muse, varscan2
- ACTN1 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV51990042; called by muse, mutect2, varscan2
- ACTN2 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV63973892; called by muse, mutect2, varscan2
- ACTN2 | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs765747662, COSV63972475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN3 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs368333449; called by muse, mutect2, varscan2
- ACTR1B | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775845413, COSV56703657; called by muse, mutect2, varscan2
- ACTR2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.804); catalogued as rs1440834418, COSV53200285; called by muse, mutect2, varscan2
- ACTR8 | c.1797G>T p.Q599H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as COSV51635869; called by muse, mutect2, varscan2
- ACTRT1 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64419147; called by muse, mutect2, varscan2
- ACVR1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554387941, COSV55117794; called by muse, mutect2, varscan2
- ACVR1C | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs754724051, COSV54645224; called by muse, mutect2, varscan2
- ACVR2A | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749174459, COSV54020819, COSV54025228; called by muse, mutect2, varscan2
- ACVR2B | c.1457A>T p.N486I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV61701860; called by muse, mutect2, varscan2
- ADAD1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as COSV56641551, COSV56642658; called by muse, varscan2
- ADAM12 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64104580; called by muse, mutect2, varscan2
- ADAM17 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV60398207; called by muse, varscan2
- ADAM19 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs781236416, COSV57426938; called by muse, mutect2, varscan2
- ADAM20 | c.431A>C p.E144A | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56454577; called by muse, mutect2, varscan2
- ADAM21 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV50790550; called by muse, varscan2
- ADAM21 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV50790579; called by muse, varscan2
- ADAM22 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55973781; called by muse, mutect2, varscan2
- ADAM23 | c.2470T>C p.F824L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV52211700; called by muse, mutect2, varscan2
- ADAM30 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs369903502; called by muse, mutect2, varscan2
- ADAM33 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV62934301; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAM7 | c.1415T>C p.M472T | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV51537741, COSV51546414; called by muse, mutect2, varscan2
- ADAM7 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs777631956, COSV51535626; called by muse, varscan2
- ADAM9 | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65959594; called by muse, mutect2, varscan2
- ADAMTS12 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV61254856; called by muse, mutect2, varscan2
- ADAMTS13 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782184721, COSV63020827; called by muse, mutect2, varscan2
- ADAMTS13 | c.3194T>C p.V1065A | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV63020831; called by mutect2, varscan2
- ADAMTS14 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs201809345, COSV64599410; called by muse, mutect2, varscan2
- ADAMTS14 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1490606457, COSV64601070; called by muse, mutect2, varscan2
- ADAMTS14 | c.2940C>A p.C980* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV64601076; called by muse, mutect2, varscan2
- ADAMTS14 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs778477923, COSV64601084; called by muse, mutect2, varscan2
- ADAMTS14 | c.3476C>T p.S1159F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64601091; called by muse, mutect2, varscan2
- ADAMTS16 | c.2355C>A p.Y785* | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | catalogued as COSV56984205; called by muse, mutect2, varscan2
- ADAMTS16 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV56984260; called by muse, mutect2, varscan2
- ADAMTS19 | c.3485G>A p.R1162K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50739654; called by muse, mutect2, varscan2
- ADAMTS2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs200022037, COSV52365296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201052588; called by muse, mutect2, varscan2
- ADAMTS20 | c.5042G>A p.C1681Y | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755728439, COSV67129639; called by muse, mutect2, varscan2
- ADAMTS20 | c.1055A>C p.D352A | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67129653; called by muse, mutect2, varscan2
- ADAMTS3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs762763954, COSV54388746; called by muse, mutect2, varscan2
- ADAMTS4 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1445185625, COSV100917490, COSV63487589; called by muse, mutect2, varscan2
- ADAMTS6 | c.3224C>T p.T1075I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as CM142273, COSV100068747, COSV58682415; called by muse, mutect2, varscan2
- ADAMTS6 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs746668287, COSV66858574, COSV66860426; called by muse, varscan2
- ADAMTS8 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV57292474; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs369442212; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4273G>C p.V1425L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV65877486; called by muse, mutect2, varscan2
- ADAMTSL2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764516811, CM113726, COSV63203217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB1 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100653643; called by muse, mutect2, varscan2
- ADAT1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57186020; called by muse, mutect2, varscan2
- ADAT1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs1340551366, COSV57186033; called by muse, mutect2, varscan2
- ADCK1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.159); catalogued as COSV99451190; called by muse, mutect2, varscan2
- ADCK1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200211943, COSV53079681; called by muse, mutect2, varscan2
- ADCY1 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1481166860, COSV52032658; called by muse, mutect2, varscan2
- ADCY10 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780855146, COSV63239657, COSV63240595; called by muse, mutect2, varscan2
- ADCY3 | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV53166061; called by muse, mutect2, varscan2
- ADCY3 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV53166073; called by muse, mutect2, varscan2
- ADCY4 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs150756728; called by muse, mutect2, varscan2
- ADCY4 | c.2059A>G p.T687A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60252393; called by muse, mutect2, varscan2
- ADCY7 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs141712991; called by muse, mutect2, varscan2
- ADCY8 | c.1588T>G p.W530G | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53902961; called by muse, mutect2, varscan2
- ADCY8 | c.1228T>C p.Y410H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53902971; called by muse, mutect2, varscan2
- ADCY8 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV53902980; called by muse, mutect2
- ADCY9 | c.3210C>A p.F1070L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV53573775; called by muse, mutect2, varscan2
- ADCY9 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs779084996, COSV53571472; called by muse, mutect2, varscan2
- ADCY9 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53573799; called by muse, varscan2
- ADCY9 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53573822; called by muse, mutect2, varscan2
- ADCY9 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV53573279; called by muse, mutect2, varscan2
- ADD2 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV52458319; called by muse, mutect2, varscan2
- ADD3 | c.1892G>A p.G631D (on ENST00000356080 / NM_001320591.2; = p.G599D on NM_001121.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53321546; called by muse, mutect2, varscan2
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- ADGRB1 | c.2289C>A p.Y763* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV60094223; called by muse, mutect2, varscan2
- ADGRB3 | c.3518C>A p.S1173Y | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV53240104, COSV99484539; called by muse, mutect2, varscan2
- ADGRD1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs377562590; called by muse, mutect2, varscan2
- ADGRE2 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs770498865, COSV59692706; called by muse, mutect2, varscan2
- ADGRE5 | c.23-1G>T p.X8_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54409619; called by muse, mutect2, varscan2
- ADGRF4 | c.60A>C p.E20D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV51951062; called by muse, mutect2, varscan2
- ADGRF5 | c.4034T>A p.L1345H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51932164; called by muse, mutect2, varscan2
- ADGRG1 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs202092636; called by muse, mutect2, varscan2
- ADGRG2 | c.2093C>G p.A698G (on ENST00000379869 / NM_001079858.3; = p.A695G on NM_005756.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100491975; called by muse, mutect2, varscan2
- ADGRG4 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1434175175, COSV54953097; called by muse, varscan2
- ADGRG4 | c.6697T>C p.S2233P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as rs1346746900, COSV54953121; called by muse, mutect2, varscan2
- ADGRG4 | c.8597C>T p.A2866V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV54953138; called by muse, mutect2, varscan2
- ADGRG5 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1228478117, COSV61082957; called by muse, mutect2, varscan2
- ADGRG6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs756610632, COSV51589664; called by muse, mutect2, varscan2
- ADGRG6 | c.3098T>C p.F1033S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51589687; called by muse, mutect2, varscan2
- ADGRG6 | c.3344G>A p.C1115Y | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51601335, COSV99746180; called by muse, mutect2
- ADGRG7 | c.2341A>C p.S781R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV56295264; called by muse, mutect2, varscan2
- ADGRL3 | c.530C>T p.P177L (on ENST00000506720 / NM_001322402.2; = p.P109L on NM_015236.6) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766951668, COSV101547446, COSV72267536; called by muse, varscan2
- ADGRL3 | c.1157G>A p.G386E (on ENST00000506720 / NM_001322402.2; = p.G318E on NM_015236.6) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267540; called by muse, mutect2, varscan2
- ADGRL3 | c.3097C>A p.L1033I (on ENST00000506720 / NM_001322402.2; = p.L965I on NM_015236.6) | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV72230134; called by muse, mutect2, varscan2
- ADGRL3 | c.3721C>T p.R1241* (on ENST00000506720 / NM_001322402.2; = p.R1173* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV72230441; called by muse, mutect2
- ADGRL4 | c.1511C>A p.A504D | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66060881; called by muse, mutect2, varscan2
- ADGRV1 | c.2765A>G p.N922S | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101315582; called by muse, mutect2
- ADGRV1 | c.3631T>C p.S1211P | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67982648; called by muse, mutect2, varscan2
- ADGRV1 | c.12517G>A p.A4173T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs759199541, COSV67982658; called by muse, mutect2, varscan2
- ADGRV1 | c.13669G>A p.V4557I | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV67982662; called by muse, mutect2, varscan2
- ADGRV1 | c.18692G>T p.S6231I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV67982668; called by muse, mutect2, varscan2
- ADH5 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs947374471, COSV56448629; called by muse, mutect2
- ADH6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs61755961, COSV52955791; called by muse, mutect2, varscan2
- ADIRF | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.289); catalogued as COSV64394098; called by muse, mutect2, varscan2
- ADNP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV62424517; called by muse, mutect2, varscan2
- ADRA1A | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as rs777863824, COSV52360695; called by muse, mutect2, varscan2
- ADRA1B | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs755458903, COSV60701200; called by muse, mutect2, varscan2
- ADRB2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60005320; called by muse, mutect2, varscan2
- ADRM1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV53355338, COSV53357036; called by muse, mutect2, varscan2
- ADSS1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289084888, COSV58272894; called by muse, mutect2, varscan2
- AFAP1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV61794753; called by muse, mutect2, varscan2
- AFAP1L2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV58413629; called by muse, mutect2, varscan2
- AFDN | c.3587A>G p.K1196R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.083); catalogued as COSV60041815; called by muse, mutect2, varscan2
- AFDN | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs200475003; called by muse, mutect2, varscan2
- AFDN | c.4211T>C p.V1404A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60041864; called by muse, mutect2, varscan2
- AFF1 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57118563; called by muse, mutect2, varscan2
- AFF4 | c.2297G>T p.R766M | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54793368; called by muse, mutect2, varscan2
- AFG1L | c.141C>A p.A47= | Splice Region (SNP) | VAF 40/62 reads (65%) | catalogued as COSV64555235; called by muse, mutect2, varscan2
- AFM | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56919630; called by muse, mutect2, varscan2
- AFP | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.636); catalogued as COSV56924549; called by muse, mutect2, varscan2
- AFP | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV56924560; called by mutect2, varscan2
- AGAP2 | c.1315+1G>A p.X439_splice (on ENST00000547588 / NM_001122772.2; = p.X103_splice on NM_014770.4) | Splice Site (SNP) | VAF 26/66 reads (39%) | catalogued as COSV57727555; called by muse, mutect2, varscan2
- AGAP3 | c.866C>T p.T289M (on ENST00000622464; = p.T325M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs191096334, COSV58994099; called by muse, mutect2, varscan2
- AGBL2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750588811, COSV54091149; called by muse, mutect2, varscan2
- AGGF1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 127/305 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771680347, COSV57228435; called by muse, mutect2, varscan2
- AGK | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as rs863223892, COSV62594172; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGL | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as CD961746, COSV54050939; called by muse, mutect2, varscan2
- AGO2 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV55046462; called by muse, varscan2
- AGO3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs372940279; called by muse, mutect2, varscan2
- AGO4 | c.1566G>A p.A522= | Splice Region (SNP) | VAF 8/68 reads (12%) | catalogued as rs569995605, COSV64616808; called by mutect2, varscan2
- AGPAT4 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs370713321, COSV57244834, COSV57249176; called by muse, mutect2, varscan2
- AGRN | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs761623497, COSV65068804; called by muse, mutect2, varscan2
- AGRN | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.688); catalogued as rs552188603, COSV65068811; called by muse, mutect2, varscan2
- AGTPBP1 | c.2569-1G>T p.X857_splice (on ENST00000357081 / NM_001330701.2; = p.X817_splice on NM_015239.2) | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV61270257; called by muse, mutect2, varscan2
- AGXT | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56753581; called by muse, mutect2, varscan2
- AHCTF1 | c.3727C>T p.R1243* (on ENST00000366508; = p.R1217* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 64/221 reads (29%) | catalogued as rs763622332, COSV58248284; called by muse, mutect2, varscan2
- AHCTF1 | c.2590C>A p.L864I (on ENST00000366508; = p.L838I on NM_015446.5) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV58248294; called by muse, mutect2, varscan2
- AHCY | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs116262714, COSV54153808; called by muse, varscan2
- AHNAK2 | c.14023G>A p.G4675S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.205); catalogued as COSV60912149; called by muse, mutect2, varscan2
- AHNAK2 | c.13338G>T p.E4446D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.832); catalogued as COSV60912159; called by muse, mutect2, varscan2
- AHNAK2 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as rs751434021, COSV60912192; called by muse, mutect2, varscan2
- AHR | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54122611; called by muse, mutect2, varscan2
- AHRR | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV57084552; called by muse, mutect2, varscan2
- AHSA1 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53631641; called by muse, varscan2
- AIFM1 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54853798; called by muse, mutect2, varscan2
- AIM2 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 115/277 reads (42%) | catalogued as rs145420527; called by muse, mutect2, varscan2
- AIMP2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52237966; called by muse, mutect2, varscan2
- AK4 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.429); catalogued as COSV100519803; called by muse, mutect2, varscan2
- AK5 | c.312C>A p.F104L (on ENST00000354567 / NM_174858.3; = p.F78L on NM_012093.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.754); catalogued as COSV58355241; called by muse, mutect2, varscan2
- AK5 | c.1354C>T p.L452F (on ENST00000354567 / NM_174858.3; = p.L426F on NM_012093.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV60970800; called by muse, mutect2, varscan2
- AK7 | c.1357+2T>C p.X453_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV50870384; called by muse, mutect2, varscan2
- AK9 | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV69850308; called by muse, mutect2, varscan2
- AKAP1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1371896079, COSV58469479; called by muse, mutect2, varscan2
- AKAP4 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs150206539, COSV62074125; called by muse, mutect2, varscan2
- AKAP4 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV62074130; called by muse, mutect2, varscan2
- AKAP6 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55210070; called by muse, mutect2, varscan2
- AKAP6 | c.6087A>C p.E2029D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV99799033; called by muse, mutect2
- AKAP9 | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.743); catalogued as COSV62342881; called by muse, mutect2, varscan2
- AKAP9 | c.5320A>G p.T1774A (on ENST00000359028; = p.T1742A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV62342887; called by muse, mutect2
- AKAP9 | c.5734C>T p.R1912C (on ENST00000359028; = p.R1880C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs761946454, COSV62342900; called by muse, mutect2, varscan2
- AKAP9 | c.11431C>T p.R3811* (on ENST00000359028; = p.R3787* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 117/230 reads (51%) | catalogued as rs183257184, COSV62342914; called by muse, mutect2, varscan2
- AKR1B15 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71151479; called by muse, mutect2, varscan2
- AKR1C1 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs782207877, COSV66498525; called by mutect2, varscan2
- AKR1C4 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs782021045, COSV54122892; called by muse, mutect2, varscan2
- AKR1D1 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253925779, COSV54337009; called by muse, mutect2, varscan2
- AKT2 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1422114933, COSV60908072; called by muse, mutect2, varscan2
- AKT3 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55612739; called by muse, mutect2, varscan2
- AKT3 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV55612770; called by muse, mutect2, varscan2
- AL592490.1 | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69425542, COSV69426626; called by muse, mutect2, varscan2
- ALAS1 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59627462; called by muse, mutect2, varscan2
- ALAS2 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100238556, COSV58189379; called by muse, mutect2, varscan2
- ALCAM | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762013509, COSV60246876; called by muse, mutect2, varscan2
- ALDH18A1 | c.2359C>A p.L787I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV64662381; called by muse, mutect2, varscan2
- ALDH18A1 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV64662386; called by muse, mutect2, varscan2
- ALDH18A1 | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs1417635601, COSV64662394; called by muse, mutect2, varscan2
- ALDH1B1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV66619510; called by muse, mutect2, varscan2
- ALDH1L1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs763483275, COSV56412618; called by muse, mutect2, varscan2
- ALDH1L2 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs778654002, COSV51554714; called by muse, mutect2, varscan2
- ALDH3B2 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.251); catalogued as COSV62427924; called by mutect2, varscan2
- ALDH6A1 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV63246118; called by muse, mutect2, varscan2
- ALDOB | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66397634; called by muse, mutect2, varscan2
- ALG13 | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52637368; called by muse, varscan2
- ALG6 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752244400, COSV54644013; called by muse, mutect2, varscan2
- ALG8 | c.1214T>G p.I405S | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs774238395, COSV55199902; called by muse, mutect2, varscan2
- ALG8 | c.697T>G p.F233V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV100220008; called by muse, mutect2
- ALKBH6 | c.448G>T p.E150* (on ENST00000252984 / NM_001297701.2; = p.E178* on NM_032878.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as rs758745205, COSV53323967, COSV53324364; called by muse, mutect2, varscan2
- ALMS1 | c.4292A>G p.H1431R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV52507051; called by muse, mutect2, varscan2
- ALMS1 | c.6704A>C p.K2235T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52507062; called by muse, mutect2, varscan2
- ALOX12 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52349322; called by muse, varscan2
- ALOX12B | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV59870999; called by muse, mutect2, varscan2
- ALOX12B | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs561140227, COSV59872136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs868318076, COSV53397040; called by muse, mutect2, varscan2
- ALPI | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs540160192, COSV55014117; called by muse, varscan2
- ALPI | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767122676, COSV55014126; called by muse, varscan2
- ALPK1 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV51583735; called by muse, mutect2, varscan2
- ALPK1 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV51583741; called by muse, mutect2, varscan2
- ALPK3 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV51931943; called by muse, mutect2, varscan2
- ALPK3 | c.2479G>C p.V827L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV51931960; called by muse, mutect2, varscan2
- ALPP | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766569752, COSV67396119; called by muse, mutect2, varscan2
- ALX1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57491817; called by muse, mutect2, varscan2
- AMBN | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs141401324; called by muse, mutect2, varscan2
- AMBRA1 | c.2019G>T p.E673D (on ENST00000458649 / NM_001367468.1; = p.E583D on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV54051531; called by muse, mutect2, varscan2
- AMBRA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54051543; called by muse, mutect2, varscan2
- AMDHD1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV57138267; called by muse, mutect2, varscan2
- AMER1 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.188); catalogued as COSV57658242; called by muse, mutect2, varscan2
- AMER1 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs754938624, COSV57658266; called by muse, mutect2, varscan2
- AMER3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778664237, COSV58465964; called by muse, mutect2, varscan2
- AMER3 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.471); catalogued as COSV58465971; called by muse, varscan2
- AMIGO2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs778977083, COSV56973856; called by mutect2, varscan2
- AMOTL1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1161931337, COSV58565831; called by muse, mutect2, varscan2
- AMOTL2 | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51438496; called by muse, mutect2, varscan2
- AMPD1 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1273170766, COSV62415623; called by muse, mutect2, varscan2
- AMPD1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752158310, COSV62415035; called by muse, mutect2, varscan2
- AMPD1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1211976677, COSV62415632; called by muse, mutect2, varscan2
- AMPH | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs766808058, COSV57738609; called by muse, mutect2, varscan2
- AMY2B | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs558190271, COSV63714832; called by muse, varscan2
- ANAPC10 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58739104; called by muse, varscan2
- ANAPC5 | c.1195A>T p.M399L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55842165; called by muse, mutect2, varscan2
- ANAPC7 | c.1163G>T p.R388I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71443783; called by muse, mutect2, varscan2
- ANAPC7 | c.387T>G p.S129R | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV71443784; called by muse, mutect2, varscan2
- ANGEL1 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51872631; called by muse, mutect2, varscan2
- ANGPT2 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57336111; called by muse, mutect2, varscan2
- ANGPT2 | c.514A>C p.K172Q | Missense Mutation (SNP) | VAF 211/864 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57336130; called by muse, mutect2, varscan2
- ANGPTL1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs374600280; called by muse, varscan2
- ANGPTL1 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141519919; called by muse, mutect2, varscan2
- ANGPTL1 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV52365929, COSV52368387; called by muse, mutect2, varscan2
- ANGPTL2 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); catalogued as COSV52219593; called by muse, mutect2, varscan2
- ANK1 | c.4306C>T p.R1436* | Nonsense Mutation (SNP) | VAF 75/112 reads (67%) | catalogued as CM960065, COSV55878288; called by muse, varscan2
- ANK1 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 102/151 reads (68%) | catalogued as COSV55878306; called by muse, mutect2, varscan2
- ANK1 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs769870526, COSV55878317; called by muse, mutect2, varscan2
- ANK2 | c.5603C>A p.P1868H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV52154478; called by muse, mutect2, varscan2
- ANK2 | c.7516C>T p.R2506W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs535569173, COSV52154500; called by muse, mutect2, varscan2
- ANK2 | c.8062C>T p.R2688* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as rs765199439, COSV52154516; called by muse, mutect2, varscan2
- ANK2 | c.11246T>G p.V3749G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.234); catalogued as COSV52154524, COSV52187302; called by muse, varscan2
- ANK3 | c.12917C>T p.S4306F (on ENST00000280772 / NM_001320874.2; = p.S930F on NM_001149.3) | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV55051539, COSV55079656; called by muse, mutect2, varscan2
- ANK3 | c.12712A>G p.T4238A (on ENST00000280772 / NM_001320874.2; = p.T862A on NM_001149.3) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1419723600, COSV55051557; called by muse, mutect2, varscan2
- ANK3 | c.10769A>G p.D3590G | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV55051577; called by muse, mutect2, varscan2
- ANK3 | c.6065C>A p.A2022D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); catalogued as COSV55051592; called by muse, mutect2, varscan2
- ANK3 | c.4856C>T p.T1619M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs778232100, COSV55049433; called by muse, mutect2, varscan2
- ANK3 | c.4592C>T p.T1531M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1415381391, COSV55051615; called by muse, mutect2, varscan2
- ANK3 | c.3991T>A p.F1331I (on ENST00000280772 / NM_001320874.2; = p.F465I on NM_001149.3) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55051627; called by muse, varscan2
- ANK3 | c.3985C>T p.R1329* (on ENST00000280772 / NM_001320874.2; = p.R463* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55051656; called by muse, varscan2
- ANK3 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1435545492, COSV55062009; called by muse, mutect2
- ANKAR | c.4164G>T p.K1388N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51462116, COSV51463534; called by muse, varscan2
- ANKEF1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs754580317, COSV65692202; called by muse, mutect2, varscan2
- ANKEF1 | c.2006C>T p.T669I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV65692208; called by muse, mutect2, varscan2
- ANKFN1 | c.1799A>G p.H600R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV59444661; called by muse, mutect2, varscan2
- ANKFY1 | c.1847A>C p.N616T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100492334; called by muse, mutect2
- ANKFY1 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV58916260; called by muse, mutect2, varscan2
- ANKH | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.542); catalogued as rs1190164920, COSV52479201; called by muse, mutect2, varscan2
- ANKK1 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV58271141; called by muse, mutect2, varscan2
- ANKK1 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV58271163; called by muse, mutect2, varscan2
- ANKLE2 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764142764, COSV61708663; called by muse, varscan2
- ANKMY1 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV56032119; called by mutect2, varscan2
- ANKRD11 | c.7402G>A p.E2468K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV56358745; called by muse, mutect2, varscan2
- ANKRD12 | c.3461A>C p.K1154T | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50821875; called by muse, mutect2, varscan2
- ANKRD13A | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1449473254, COSV55675874; called by muse, mutect2, varscan2
- ANKRD13B | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as rs774030034, COSV67473645; called by muse, mutect2, varscan2
- ANKRD17 | c.6980C>T p.S2327L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.116); catalogued as rs773766530, COSV58217858; called by muse, mutect2, varscan2
- ANKRD17 | c.5031A>C p.E1677D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV100428673; called by muse, mutect2
- ANKRD17 | c.4645A>G p.T1549A | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.012); catalogued as COSV58218256; called by muse, mutect2, varscan2
- ANKRD17 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.963); catalogued as rs559559415, COSV58218260; called by muse, mutect2, varscan2
- ANKRD22 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758073859, COSV64236209; called by muse, mutect2, varscan2
- ANKRD26 | c.3307C>A p.Q1103K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV65774836; called by muse, mutect2, varscan2
- ANKRD26 | c.1077+1G>A p.X359_splice | Splice Site (SNP) | VAF 50/122 reads (41%) | catalogued as COSV65793705; called by muse, mutect2, varscan2
- ANKRD28 | c.1609T>G p.S537A | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV67517491; called by muse, mutect2, varscan2
- ANKRD30A | c.1565C>T p.A522V (on ENST00000611781; = p.A466V on NM_052997.2) | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV64607926; called by muse, mutect2, varscan2
- ANKRD34A | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60160643; called by muse, mutect2, varscan2
- ANKRD37 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.945); catalogued as rs759561906, COSV52991184; called by muse, mutect2, varscan2
- ANKRD50 | c.4113C>G p.S1371R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as COSV72385362; called by muse, mutect2, varscan2
- ANKRD50 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs763266709, COSV72385175; called by muse, mutect2, varscan2
- ANKRD52 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1368235699, COSV57285494; called by muse, mutect2
- ANKRD52 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV57283569; called by muse, mutect2, varscan2
- ANKS1B | c.3206C>A p.S1069Y (on ENST00000547776 / NM_152788.4; = p.S235Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59116214; called by muse, mutect2, varscan2
- ANKS1B | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs374815422, COSV61353917; called by muse, mutect2, varscan2
- ANKS3 | c.1828G>T p.A610S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV58508328; called by muse, mutect2, varscan2
- ANKS6 | c.2464T>C p.S822P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.422); catalogued as COSV62049808; called by muse, varscan2
- ANKZF1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV55476039; called by muse, mutect2, varscan2
- ANLN | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56075036; called by muse, mutect2, varscan2
- ANO1 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60283107; called by muse, mutect2, varscan2
- ANO1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1476234926, COSV60283119; called by muse, mutect2, varscan2
- ANO2 | c.2383G>T p.D795Y (on ENST00000356134 / NM_001278597.3; = p.D799Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59015635; called by muse, mutect2, varscan2
- ANO3 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV56786833; called by muse, mutect2, varscan2
- ANO4 | c.1862A>G p.H621R (on ENST00000392977 / NM_001286615.2; = p.H586R on NM_178826.4) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV54591404; called by muse, mutect2, varscan2
- ANO4 | c.2437G>T p.E813* (on ENST00000392977 / NM_001286615.2; = p.E778* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV54591417; called by muse, mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- ANO5 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61083735; called by muse, mutect2, varscan2
- ANO6 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57659411; called by muse, mutect2, varscan2
- ANO6 | c.2246T>C p.M749T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs749585156, COSV57659427; called by muse, mutect2, varscan2
- ANO7 | c.1137A>G p.I379M (on ENST00000274979; = p.I325M on NM_001370694.2) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV51470281; called by muse, mutect2, varscan2
- ANO8 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217218837, COSV50174904; called by mutect2, varscan2
- ANOS1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs199725550, COSV52915809; called by muse, mutect2, varscan2
- ANTXR1 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV58011851; called by muse, mutect2, varscan2
- ANXA1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99973838; called by muse, mutect2, varscan2
- ANXA10 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs755143505, COSV63738646; called by muse, mutect2, varscan2
- ANXA2 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV60316208; called by muse, mutect2, varscan2
- ANXA4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs770362785, COSV67848640; called by muse, mutect2, varscan2
- ANXA5 | c.227A>T p.K76I | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV56638651, COSV99634425; called by muse, mutect2, varscan2
- ANXA6 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs545945295, COSV62906173; called by muse, mutect2, varscan2
- ANXA7 | c.1375G>A p.A459T (on ENST00000372919 / NM_001320880.2; = p.A437T on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs146521289; called by muse, mutect2, varscan2
- ANXA9 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV64484548; called by muse, varscan2
- AOAH | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51738411; called by muse, mutect2, varscan2
- AOAH | c.289C>T p.L97= | Splice Region (SNP) | VAF 86/169 reads (51%) | catalogued as COSV51738418; called by muse, mutect2, varscan2
- AOX1 | c.1669C>A p.H557N | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65980894; called by muse, mutect2, varscan2
- AOX1 | c.3236C>T p.T1079I | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV53495710; called by muse, mutect2, varscan2
- AP000311.1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs763737878, COSV51708180; called by muse, mutect2, varscan2
- AP002748.5 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as rs769090687, COSV59147887, COSV59151279; called by muse, mutect2, varscan2
- AP1B1 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016229; called by muse, mutect2, varscan2
- AP1M2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746080407, COSV51566567; called by muse, mutect2, varscan2
- AP2A2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV59959455; called by muse, mutect2, varscan2
- AP2A2 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1202751921, COSV59959470; called by muse, mutect2, varscan2
- AP2M1 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53047623; called by muse, mutect2, varscan2
- AP3D1 | c.3261G>T p.K1087N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV61426373; called by muse, mutect2, varscan2
- AP3D1 | c.3164+1G>A p.X1055_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV61426394; called by muse, mutect2, varscan2
- APAF1 | c.614G>A p.R205Q (on ENST00000551964 / NM_181861.2; = p.R194Q on NM_001160.3) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309940307, COSV59663007; called by muse, mutect2, varscan2
- APAF1 | c.3649G>T p.G1217* (on ENST00000551964 / NM_181861.2; = p.G1163* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as COSV59117096; called by muse, mutect2, varscan2
- APBA2 | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV67104486; called by muse, mutect2, varscan2
- APBB1IP | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV66131278; called by muse, mutect2, varscan2
- APBB2 | c.835G>A p.D279N (on ENST00000295974 / NM_001166050.2; = p.A279T on NM_004307.2) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55950211; called by muse, mutect2, varscan2
- APC | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.194); catalogued as rs748193367, COSV57335627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1554079159, COSV57335635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5675C>T p.A1892V | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs759914956, COSV57335654; called by muse, mutect2, varscan2
- APIP | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV53506474; called by muse, mutect2, varscan2
- APLF | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769480335, COSV100377003, COSV58143504; called by muse, varscan2
- APLF | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV58143867; called by muse, varscan2
- APLP2 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761914771, COSV53840048; called by muse, mutect2, varscan2
- APOB | c.8530C>A p.L2844M | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV51930748; called by muse, mutect2, varscan2
- APOB | c.7559G>A p.R2520Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199852015, COSV99028579; called by muse, mutect2
- APOB | c.5044A>G p.M1682V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs140858817, COSV51930761; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.3506A>G p.Y1169C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51930775; called by muse, mutect2, varscan2
- APOB | c.2287A>G p.K763E | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1398175728, COSV51930791; called by muse, mutect2, varscan2
- APOB | c.1880T>G p.V627G | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99264171; called by muse, mutect2
- APOBEC2 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV55142343; called by muse, mutect2, varscan2
- APOBEC3F | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57910195; called by muse, mutect2, varscan2
- APOBR | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs578246087, COSV60489768; called by muse, mutect2, varscan2
- APOH | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52772010, COSV52772599; called by muse, mutect2, varscan2
- APOL4 | c.301G>T p.E101* (on ENST00000352371 / NM_145660.2; = p.E98* on NM_030643.4) | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV60654312; called by muse, mutect2, varscan2
- APOL5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs768415716, COSV50766598; called by muse, mutect2, varscan2
- APOL6 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs368078894, COSV68749429; called by mutect2, varscan2
- APPL1 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs778141780, COSV55699431; called by muse, mutect2, varscan2
- APPL2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as rs1314012568, COSV51588026; called by muse, mutect2, varscan2
- APPL2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1032902795, COSV51589391; called by muse, mutect2, varscan2
- AQP10 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61474750; called by muse, mutect2, varscan2
- AQP4 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1166313518, COSV67218412; called by muse, mutect2, varscan2
- AQP6 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV59646161; called by muse, mutect2, varscan2
- AQP7 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs575153087, COSV53011463; called by muse, mutect2, varscan2
- ARAF | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1321474185, COSV51692062; called by muse, varscan2
- ARAP2 | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs771336636, COSV58284967; called by muse, varscan2
- ARAP2 | c.3862G>T p.D1288Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778593463, COSV58284975; called by muse, mutect2, varscan2
- ARAP2 | c.1810T>G p.F604V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV58284983; called by muse, mutect2, varscan2
- ARAP2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.51); catalogued as rs144707231; called by muse, mutect2, varscan2
- ARC | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV63078323; called by muse, mutect2, varscan2
- ARF4 | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57714788; called by muse, mutect2, varscan2
- ARF5 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV50000551, COSV50000660; called by muse, mutect2, varscan2
- ARFGAP2 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.424); catalogued as COSV60300779; called by muse, mutect2, varscan2
- ARFGAP3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs376025653, COSV54311295; called by muse, mutect2, varscan2
- ARFGEF1 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs146133956, COSV51605657; called by muse, mutect2, varscan2
- ARFGEF1 | c.3412A>C p.N1138H | Missense Mutation (SNP) | VAF 144/192 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV51605840; called by muse, varscan2
- ARFGEF1 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as rs1250094954, COSV51605863; called by muse, mutect2, varscan2
- ARFGEF1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369515490, COSV51604648; called by muse, mutect2, varscan2
- ARFGEF2 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV64211583; called by mutect2, varscan2
- ARFGEF3 | c.2510C>T p.S837L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1390837312, COSV52454532, COSV99292218; called by muse, mutect2, varscan2
- ARFGEF3 | c.3601C>T p.L1201F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52454546; called by muse, mutect2, varscan2
- ARFGEF3 | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1463417276, COSV52454572; called by muse, mutect2, varscan2
- ARFIP1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as COSV61883914, COSV61883968; called by muse, mutect2, varscan2
- ARG1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV51580819; called by muse, mutect2, varscan2
- ARG1 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.483); catalogued as COSV51580827; called by muse, mutect2, varscan2
- ARHGAP10 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.058); catalogued as rs781755822, COSV60597231; called by muse, mutect2, varscan2
- ARHGAP11A | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 48/105 reads (46%) | catalogued as rs756869901, COSV64380781; called by muse, mutect2, varscan2
- ARHGAP11A | c.2675C>A p.S892Y | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.365); catalogued as COSV55705781; called by muse, mutect2, varscan2
- ARHGAP11B | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs1421479155, COSV70288336; called by muse, mutect2, varscan2
- ARHGAP12 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 53/117 reads (45%) | catalogued as rs1253512015, COSV60962468; called by muse, mutect2, varscan2
- ARHGAP12 | c.2155A>C p.K719Q | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as COSV60962486; called by muse, mutect2, varscan2
- ARHGAP15 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.642); catalogued as rs1034784190, COSV54488590; called by muse, mutect2, varscan2
- ARHGAP17 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV51505974; called by muse, mutect2, varscan2
- ARHGAP17 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs149340407, COSV51505989; called by muse, mutect2, varscan2
- ARHGAP17 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754194639, COSV51506001; called by muse, varscan2
- ARHGAP19 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV57392219; called by muse, mutect2, varscan2
- ARHGAP20 | c.3016T>A p.S1006T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52809209; called by muse, mutect2, varscan2
- ARHGAP20 | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52809228; called by muse, mutect2, varscan2
- ARHGAP21 | c.4228G>C p.V1410L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV57604362; called by muse, mutect2, varscan2
- ARHGAP21 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57604424; called by muse, mutect2, varscan2
- ARHGAP24 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374671512; called by muse, mutect2, varscan2
- ARHGAP24 | c.1212G>T p.K404N (on ENST00000395184 / NM_001025616.3; = p.K311N on NM_031305.3) | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51988069; called by muse, mutect2, varscan2
- ARHGAP25 | c.215C>T p.A72V (on ENST00000409202 / NM_001007231.3; = p.A65V on NM_014882.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs201284610, COSV54900887; called by muse, mutect2, varscan2
- ARHGAP29 | c.1886G>A p.G629D | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV53108463, COSV53110252; called by muse, mutect2, varscan2
- ARHGAP30 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1386144677, COSV63515785; called by muse, mutect2, varscan2
- ARHGAP30 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63515788, COSV63519415; called by muse, mutect2, varscan2
- ARHGAP31 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV51791194; called by muse, mutect2, varscan2
- ARHGAP31 | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV51791200; called by muse, mutect2, varscan2
- ARHGAP32 | c.4207C>T p.P1403S (on ENST00000310343 / NM_001378025.1; = p.P1054S on NM_014715.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV59845706; called by muse, mutect2, varscan2
- ARHGAP35 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs1324454897, COSV68329190; called by muse, mutect2, varscan2
- ARHGAP35 | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs776487199, COSV68330316; called by muse, mutect2, varscan2
- ARHGAP35 | c.2224T>C p.Y742H | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV68330320; called by muse, mutect2, varscan2
- ARHGAP35 | c.2672G>A p.G891D | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV68330324; called by muse, mutect2, varscan2
- ARHGAP36 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52265490; called by muse, varscan2
- ARHGAP44 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as rs754270006, COSV52390410; called by muse, mutect2, varscan2
- ARHGAP5 | c.3563G>T p.R1188I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV61534800; called by muse, mutect2, varscan2
- ARHGAP6 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1569233984, COSV57294006; called by muse, mutect2, varscan2
- ARHGDIA | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV53906572; called by muse, mutect2, varscan2
- ARHGEF1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs782364939, COSV100528907; called by muse, mutect2
- ARHGEF10 | c.217G>A p.A73T (on ENST00000398564; = p.A49T on NM_014629.4) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.028); catalogued as rs559084209, COSV100034071; called by muse, mutect2, varscan2
- ARHGEF11 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 115/227 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63811413; called by muse, mutect2, varscan2
- ARHGEF12 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV63103617; called by muse, mutect2, varscan2
- ARHGEF12 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs763312257, COSV63103205; called by muse, mutect2, varscan2
- ARHGEF15 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62724801; called by muse, mutect2, varscan2
- ARHGEF15 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1337793938, COSV62724598; called by muse, mutect2, varscan2
- ARHGEF18 | c.1677G>T p.E559D (on ENST00000359920 / NM_001130955.2; = p.E455D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV60468548; called by muse, mutect2, varscan2
- ARHGEF2 | c.2747G>A p.R916H (on ENST00000361247 / NM_001162383.2; = p.R888H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.964); catalogued as rs141465288, COSV58108899; called by muse, mutect2, varscan2
- ARHGEF25 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54085612; called by muse, mutect2, varscan2
- ARHGEF28 | c.886T>A p.S296T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55252522; called by muse, mutect2, varscan2
- ARHGEF35 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV65312590; called by muse, mutect2, varscan2
- ARHGEF40 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs779458649, COSV100070553, COSV53879331; called by muse, mutect2, varscan2
- ARHGEF5 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV50208910; called by mutect2, varscan2
- ARHGEF6 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 64/143 reads (45%) | catalogued as COSV51689165, COSV99166766; called by muse, mutect2, varscan2
- ARHGEF6 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV51689176; called by muse, mutect2, varscan2
- ARHGEF7 | c.833A>C p.N278T (on ENST00000375741 / NM_001113511.2; = p.N100T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV54541448; called by muse, mutect2, varscan2
- ARHGEF7 | c.2447A>C p.E816A (on ENST00000646102 / NM_001354046.1; = p.E600A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99521130; called by muse, mutect2
- ARID1A | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61374844; called by muse, mutect2, varscan2
- ARID1A | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61374851; called by muse, mutect2, varscan2
- ARID2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs1170640220, COSV57600739; called by muse, mutect2, varscan2
- ARID2 | c.5487A>C p.K1829N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as COSV57600759; called by muse, mutect2, varscan2
- ARID4A | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62162985; called by muse, mutect2, varscan2
- ARID4B | c.3775C>T p.R1259W | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765733853, COSV51601253; called by muse, mutect2, varscan2
- ARID4B | c.1704C>A p.C568* | Nonsense Mutation (SNP) | VAF 102/304 reads (34%) | catalogued as COSV51601265; called by muse, mutect2, varscan2
- ARID4B | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 259/460 reads (56%) | catalogued as COSV51601280; called by muse, mutect2, varscan2
- ARIH2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs757397436, COSV62704332; called by muse, mutect2, varscan2
- ARL13A | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101502316; called by muse, mutect2
- ARL13B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767393160, COSV57397362, COSV57402086; called by muse, mutect2, varscan2
- ARMC2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306697843, COSV52900125; called by muse, mutect2, varscan2
- ARMC3 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV53059375, COSV53068778; called by muse, mutect2, varscan2
- ARNT2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583460; called by muse, mutect2, varscan2
- ARNTL2 | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV53824747; called by muse, mutect2, varscan2
- ARNTL2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758271274, COSV53824759; called by muse, mutect2, varscan2
- ARR3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs778493881, COSV57203793; called by muse, mutect2, varscan2
- ARSB | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53722572; called by muse, mutect2, varscan2
- ARSD | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54199119; called by muse, mutect2, varscan2
- ARSG | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs367632717, COSV71593504; called by muse, mutect2, varscan2
- ARSG | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV71592918; called by muse, mutect2, varscan2
- ARSG | c.1232G>T p.S411I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71592919; called by muse, mutect2, varscan2
- ARSJ | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV59537453; called by muse, mutect2, varscan2
- ARV1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59617445; called by muse, mutect2, varscan2
- ASAP3 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60873998; called by muse, mutect2, varscan2
- ASB1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747970208, COSV52826700; called by muse, mutect2, varscan2
- ASB15 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51924976; called by muse, mutect2, varscan2
- ASB18 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV100430841, COSV58233222; called by muse, mutect2, varscan2
- ASB4 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100367102; called by muse, mutect2, varscan2
- ASB9 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66851518; called by muse, mutect2, varscan2
- ASCC1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751027189, COSV54964273; called by muse, mutect2, varscan2
- ASCC2 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535065277, COSV57072832; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 64/168 reads (38%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASCC3 | c.3785C>A p.P1262H | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61227468, COSV61228558; called by muse, mutect2, varscan2
- ASGR2 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV54689821; called by muse, mutect2, varscan2
- ASGR2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs746739001, COSV54689831; called by muse, varscan2
- ASH1L | c.4568C>T p.A1523V | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV64206861; called by muse, mutect2, varscan2
- ASH1L | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV64208731; called by muse, mutect2
- ASH1L | c.2213G>T p.R738I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV64206864, COSV64212564; called by muse, mutect2, varscan2
- ASH1L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs867128307, COSV64205328; called by muse, mutect2, varscan2
- ASH1L | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as COSV64206869; called by muse, mutect2, varscan2
- ASIC1 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754524092, COSV57317036; called by muse, mutect2
- ASIC4 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61731441; called by muse, mutect2, varscan2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ASMTL | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs766005348, COSV67243347; called by muse, varscan2
- ASNS | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1283664547, COSV51551389, COSV51552115; called by muse, mutect2, varscan2
- ASNS | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as rs1140424, COSV51551491; called by muse, mutect2, varscan2
- ASNS | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs138299423; called by mutect2, varscan2
- ASPA | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs777440893, COSV53980706; called by muse, mutect2, varscan2
- ASPG | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs748633326, COSV71933603, COSV71934117; called by muse, mutect2, varscan2
- ASPH | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV65242699, COSV65243975; called by muse, mutect2, varscan2
- ASPH | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.265); catalogued as rs201124803, COSV100727419, COSV62858258; called by muse, mutect2, varscan2
- ASPH | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 138/309 reads (45%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as COSV62858602; called by muse, mutect2, varscan2
- ASPM | c.7187G>T p.R2396M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54127839; called by muse, mutect2, varscan2
- ASPM | c.6323G>A p.R2108K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.241); catalogued as COSV54127843, COSV99038506; called by muse, mutect2, varscan2
- ASPM | c.4897C>T p.R1633C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200202166; called by mutect2, varscan2
- ASPM | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779018406, COSV54127872; called by muse, varscan2
- ASPM | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54127887; called by muse, mutect2, varscan2
- ASPM | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs201143810, COSV54127897; called by muse, mutect2, varscan2
- ASTE1 | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV53908270; called by muse, varscan2
- ASTN1 | c.3530A>G p.Y1177C | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100705662; called by muse, mutect2
- ASTN1 | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs775285855, COSV62494683; called by muse, mutect2, varscan2
- ASTN2 | c.3473G>A p.C1158Y (on ENST00000313400 / NM_001365069.1; = p.C1107Y on NM_014010.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56002226; called by muse, mutect2, varscan2
- ASTN2 | c.1651C>T p.R551C (on ENST00000313400 / NM_001365069.1; = p.R500C on NM_014010.5) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776841753, COSV57773431; called by muse, mutect2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ASXL3 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1457535713, COSV52462566, COSV52467267; called by muse, mutect2, varscan2
- ASXL3 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV52462582; called by muse, mutect2, varscan2
- ASZ1 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52912282; called by muse, mutect2, varscan2
- ATAD1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as rs1237396309, COSV57756395; called by muse, mutect2, varscan2
- ATAD2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs772718666, COSV54879378; called by muse, mutect2, varscan2
- ATAD2 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV54879392; called by muse, mutect2, varscan2
- ATAD3A | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV59232742; called by muse, mutect2, varscan2
- ATAD3A | c.1657A>G p.K553E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV59232750; called by muse, mutect2, varscan2
- ATAD5 | c.3305A>G p.K1102R | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58973387; called by muse, varscan2
- ATAD5 | c.4078-1G>T p.X1360_splice | Splice Site (SNP) | VAF 59/118 reads (50%) | catalogued as COSV58973391; called by muse, mutect2, varscan2
- ATAD5 | c.4268G>A p.S1423N | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs959539299, COSV58973399; called by muse, mutect2, varscan2
- ATAT1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53313285; called by muse, mutect2, varscan2
- ATCAY | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1382365615, COSV56655194; called by muse, mutect2, varscan2
- ATF3 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs187549802, COSV100421971; called by muse, mutect2, varscan2
- ATF4 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs754096991, COSV100307587; called by muse, mutect2
- ATF4 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); catalogued as COSV57478425; called by muse, mutect2, varscan2
- ATF5 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370013285; called by muse, varscan2
- ATF5 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs772931728, COSV61311679; called by muse, varscan2
- ATF6 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV63406811; called by muse, mutect2, varscan2
- ATF7IP | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs766682669, COSV53768621; called by muse, mutect2, varscan2
- ATF7IP | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs138035183, COSV53768720; called by muse, mutect2, varscan2
- ATG2A | c.2691G>T p.E897D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV65966301; called by muse, mutect2, varscan2
- ATG2A | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV65966303; called by muse, mutect2, varscan2
- ATG2B | c.5839A>G p.M1947V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV55889914; called by muse, mutect2, varscan2
- ATG2B | c.4985T>G p.F1662C | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55889921; called by muse, mutect2, varscan2
- ATG4B | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV60349231, COSV60350437; called by muse, varscan2
- ATIC | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV52691504; called by muse, mutect2, varscan2
- ATM | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 52/121 reads (43%) | catalogued as COSV53736099; called by muse, mutect2, varscan2
- ATM | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV53736117; called by muse, varscan2
- ATMIN | c.1026C>A p.H342Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV55145660; called by muse, varscan2
- ATMIN | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs751306740, COSV55145672, COSV55147036; called by muse, varscan2
- ATN1 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs782577561, COSV63110199, COSV63112552; called by muse, mutect2, varscan2
- ATP10A | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763990614, COSV63515700; called by muse, mutect2, varscan2
- ATP10B | c.3299T>G p.V1100G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59147881; called by muse, mutect2, varscan2
- ATP10D | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | catalogued as COSV56705850; called by muse, mutect2, varscan2
- ATP11A | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1233411678, COSV52109311; called by muse, mutect2, varscan2
- ATP11C | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59560697, COSV59561511; called by muse, mutect2, varscan2
- ATP11C | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100558790, COSV59561740; called by muse, mutect2, varscan2
- ATP11C | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768342557, COSV59561768; called by muse, mutect2, varscan2
- ATP12A | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752833147, COSV54514578; called by muse, mutect2, varscan2
- ATP13A3 | c.2386A>G p.T796A | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV55463075; called by mutect2, varscan2
- ATP13A3 | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs1162970033, COSV55463087; called by muse, mutect2, varscan2
- ATP13A3 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55463100; called by muse, mutect2, varscan2
- ATP13A5 | c.3414T>A p.N1138K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53230778; called by muse, mutect2, varscan2
- ATP13A5 | c.1858C>T p.H620Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV60867850; called by mutect2, varscan2
- ATP13A5 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771136195, COSV60865078, COSV60873897; called by muse, mutect2, varscan2
- ATP1A1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs148719009; called by muse, mutect2, varscan2
- ATP1A2 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63403170; called by muse, mutect2, varscan2
- ATP1A2 | c.1753C>T p.L585F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV63403179, COSV63405624; called by muse, mutect2, varscan2
- ATP1A4 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63626040; called by muse, mutect2, varscan2
- ATP2A1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757752844, COSV63920538; called by muse, mutect2, varscan2
- ATP2A2 | c.1460T>G p.F487C | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014165, COSV58043382; called by muse, mutect2, varscan2
- ATP2A3 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1409645346, COSV59227866; called by muse, mutect2
- ATP2B2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs945844574, COSV59489385; called by muse, mutect2, varscan2
- ATP2B3 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54843827; called by muse, mutect2, varscan2
- ATP2B4 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as COSV58176138; called by muse, mutect2, varscan2
- ATP2B4 | c.1673C>A p.P558H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV58176158; called by muse, mutect2, varscan2
- ATP2B4 | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58176183, COSV58183959; called by muse, mutect2, varscan2
- ATP2C2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs1246302728, COSV52294296; called by muse, mutect2, varscan2
- ATP5F1B | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56260692; called by muse, mutect2, varscan2
- ATP5IF1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as COSV55281239; called by muse, mutect2, varscan2
- ATP5PF | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53166795, COSV53166867; called by muse, mutect2, varscan2
- ATP6AP2 | c.168+1G>T p.X56_splice | Splice Site (SNP) | VAF 28/68 reads (41%) | catalogued as COSV65797447; called by muse, mutect2, varscan2
- ATP6AP2 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs767631127, COSV101011576, COSV65797453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0A2 | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.636); catalogued as COSV57748510; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57748521; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57748535; called by muse, varscan2
- ATP6V0A4 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769100205, COSV59474207; called by muse, mutect2, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V0D1 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52097256; called by muse, mutect2, varscan2
- ATP6V0D2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.666); catalogued as rs777381409, COSV53414052; called by muse, mutect2, varscan2
- ATP6V1A | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56361666; called by muse, mutect2, varscan2
- ATP6V1B1 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52268885; called by muse, mutect2, varscan2
- ATP6V1B2 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52353162; called by muse, mutect2, varscan2
- ATP6V1E1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.258); catalogued as rs750759727, COSV53657616; called by muse, mutect2, varscan2
- ATP6V1H | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV62217727; called by muse, mutect2, varscan2
- ATP7A | c.2548G>T p.V850L | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100430413; called by muse, mutect2
- ATP7B | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749626601, COSV54435660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1217699790, COSV52531992; called by muse, mutect2, varscan2
- ATP8A1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372884316; called by muse, mutect2, varscan2
- ATP8A2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1349352729, COSV54945493; called by muse, mutect2, varscan2
- ATP8B1 | c.2148A>C p.E716D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV99376926; called by muse, mutect2
- ATP9A | c.2719C>A p.P907T | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV58764943; called by muse, mutect2, varscan2
- ATP9B | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 10/10 reads (100%) | catalogued as COSV56948983; called by muse, mutect2, varscan2
- ATPAF2 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71398440; called by muse, mutect2, varscan2
- ATR | c.4693A>G p.N1565D | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1005423503, COSV100637772; called by muse, mutect2
- ATR | c.4201A>G p.T1401A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV63385419; called by muse, mutect2, varscan2
- ATR | c.2836A>G p.M946V | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV63393312; called by muse, mutect2
- ATRN | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 94/231 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53525842; called by muse, mutect2, varscan2
- ATRN | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs762169974, COSV53525849; called by muse, mutect2, varscan2
- ATRNL1 | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV61801770; called by muse, mutect2, varscan2
- ATRX | c.6010G>T p.D2004Y | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV64874353, COSV64883465; called by muse, mutect2, varscan2
- ATRX | c.5486C>T p.P1829L | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64874355; called by muse, mutect2, varscan2
- ATXN1 | c.1610C>A p.A537D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV55212957, COSV55233077; called by muse, varscan2
- ATXN2 | c.2800A>G p.T934A (on ENST00000550104; = p.T774A on NM_002973.4) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV66486395; called by muse, mutect2
10,325 further variants in this file (7,513 protein-altering or splice-affecting, 2,616 silent, 196 other) are not listed here.
